Gene-level copy-number profile of tumor specimen TCGA-XV-AAZW-01A from TCGA case TCGA-XV-AAZW, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 62.4 years (22,778 days).
Specimen TCGA-XV-AAZW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.ed13f3b1-1447-47db-870a-ed2e6511554b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XV-AAZW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c2627ea3-53f5-4d66-b2f3-b720a3f09e7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 9,282; copy number 2: 47,685; copy number 3: 1,492; copy number 4: 731; copy number 5: 606.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XV-AAZW-01A-12D-A400-01): tumor purity 0.84, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:147,158,925–147,408,281, 4 genes: LUADT1, STXBP5, AL355365.1, YAP1P1.
- chr9:21,802,636–21,937,651, 1 gene (within-gene range 0–1): MTAP.
- chr9:21,858,910–21,931,073, 3 genes: AL359922.2, AL359922.3, ERVFRD-3.
- chr9:101,473,170–101,533,537, 2 genes (within-gene range 0–1): PGAP4, AL353621.1.
- chr10:87,859,158–88,584,530, 8 genes (within-gene range 0–1): KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 606 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:103,471,784–103,989,658, 1 gene, copy number 5 (within-gene range 4–5): RELN.
- chr7:104,126,341–141,841,487, 605 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,545. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
